Somatic mutation profile of tumor specimen c17b0ff9-9057-4848-a0cc-abb25f (aliquot c17b0ff9-9057-4848-a0cc-abb25f_D6) from CPTAC case 26OV010, project CPTAC-2 (Ovary — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIB.
Specimen c17b0ff9-9057-4848-a0cc-abb25f: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2ed9a306-1261-46ca-8947-b0e33d74c6b3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen c4bdeb24-c38a-421e-83eb-9d1225 (Blood Derived Normal), aliquot c4bdeb24-c38a-421e-83eb-9d1225_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/650c17e4-d419-4b83-953f-dc4ef462cd90

The open-access MAF lists 105 somatic variants for this specimen: 75 protein-altering or splice-affecting, 18 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 65, Silent 18, Intron 7, Nonsense Mutation 4, 5'Flank 3, Frame Shift Del 3, Splice Site 2, Splice Region 1, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYL2 | c.260G>C p.G87A | Missense Mutation (SNP) | VAF 131/193 reads (68%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs397516399, CM133976; ClinVar: likely pathogenic / uncertain significance; called by muse, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 192/303 reads (63%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CEACAM16 | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 87/154 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs779442965, COSV101312768; called by muse, mutect2, varscan2
- CYLC1 | c.1471G>C p.E491Q | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.858); catalogued as COSV61410052; called by muse, mutect2, varscan2
- DNAH7 | c.8503C>T p.Q2835* | Nonsense Mutation (SNP) | VAF 16/131 reads (12%) | catalogued as rs754172857; called by muse, mutect2, varscan2
- EIF4G3 | c.2980A>G p.K994E | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as rs766597088; called by muse, mutect2, varscan2
- IGHV5-51 | c.278A>G p.K93R | Missense Mutation (SNP) | VAF 107/916 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.167); catalogued as rs782648341; called by muse, mutect2, varscan2
- LAMA5 | c.10213A>G p.M3405V | Missense Mutation (SNP) | VAF 48/249 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs779411240; called by muse, mutect2, varscan2
- NF1 | c.5493G>T p.W1831C (on ENST00000358273 / NM_001042492.3; = p.W1810C on NM_000267.3) | Missense Mutation (SNP) | VAF 68/96 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as CM1311487; called by muse, mutect2, varscan2
- NPNT | c.1057G>A p.G353R | Missense Mutation (SNP) | VAF 33/225 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs756406157, COSV59751762; called by muse, mutect2, varscan2
- OR6K2 | c.554G>A p.R185H | Missense Mutation (SNP) | VAF 64/473 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.021); catalogued as rs139512724; called by muse, mutect2, varscan2
- RTL1 | c.1129C>T p.R377W | Missense Mutation (SNP) | VAF 411/699 reads (59%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs1484510513, COSV66017523; called by muse, mutect2, varscan2
- SDK2 | c.1144G>A p.A382T | Missense Mutation (SNP) | VAF 111/164 reads (68%) | SIFT deleterious (0.02); PolyPhen benign (0.421); catalogued as rs148243066, COSV66190160; called by muse, mutect2, varscan2
- SEPTIN12 | c.994C>T p.P332S | Missense Mutation (SNP) | VAF 87/346 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1330141474; called by muse, mutect2, varscan2
- TAF1 | c.2321C>G p.P774R (on ENST00000373790 / NM_138923.4; = p.P795R on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 92/273 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52112560; called by muse, mutect2, varscan2
- TLR6 | c.358A>G p.I120V | Missense Mutation (SNP) | VAF 57/157 reads (36%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs1457556098; called by muse, mutect2, varscan2
- TRAV22 | c.17G>C p.G6A | Missense Mutation (SNP) | VAF 31/164 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.049); catalogued as rs368457737; called by muse, mutect2, varscan2
- XIRP2 | c.3546G>T p.K1182N (on ENST00000628543; = p.K1357N on NM_152381.6) | Missense Mutation (SNP) | VAF 48/326 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767760428; called by muse, mutect2, varscan2
- ABCC3 | c.2963C>A p.A988D | Missense Mutation (SNP) | VAF 284/416 reads (68%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ACBD5 | c.703_715del p.V235Mfs*20 (on ENST00000375888 / NM_001352568.1; = p.V226Mfs*20 on NM_145698.5 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 45/368 reads (12%) | called by mutect2, pindel, varscan2
- ADAMTS16 | c.2804A>C p.N935T | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- ADCY8 | c.598C>T p.H200Y | Missense Mutation (SNP) | VAF 294/1526 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- AHNAK | c.12221A>T p.K4074I | Missense Mutation (SNP) | VAF 103/265 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- ARHGAP33 | c.1343C>A p.A448D | Missense Mutation (SNP) | VAF 35/211 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.523); called by muse, mutect2, varscan2
- ASB16 | c.1086C>G p.F362L | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- ASPSCR1 | c.1165C>G p.P389A | Missense Mutation (SNP) | VAF 29/163 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ATG4B | c.810T>A p.V270= | Splice Region (SNP) | VAF 71/142 reads (50%) | called by muse, mutect2, varscan2
- BHLHE40 | c.965G>A p.C322Y | Missense Mutation (SNP) | VAF 101/575 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BOC | c.1956G>C p.W652C | Missense Mutation (SNP) | VAF 80/536 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by mutect2, varscan2
- CACNA1H | c.6829A>G p.S2277G | Missense Mutation (SNP) | VAF 66/644 reads (10%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); called by muse, mutect2
- CCDC15 | c.392G>T p.S131I | Missense Mutation (SNP) | VAF 52/162 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- CHML | c.722A>C p.Q241P | Missense Mutation (SNP) | VAF 51/269 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CLRN3 | c.424G>C p.V142L | Missense Mutation (SNP) | VAF 73/327 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CNOT1 | c.248C>A p.T83K | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- COL4A5 | c.1088T>A p.L363* | Nonsense Mutation (SNP) | VAF 90/302 reads (30%) | called by muse, mutect2, varscan2
- DGKQ | c.1893C>G p.H631Q | Missense Mutation (SNP) | VAF 31/163 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DOCK11 | c.2507A>G p.Q836R | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ETV1 | c.1068G>C p.W356C | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FBXO5 | c.41G>T p.R14L | Missense Mutation (SNP) | VAF 4/65 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); called by muse, mutect2
- FOCAD | c.2718+2T>C p.X906_splice | Splice Site (SNP) | VAF 29/176 reads (16%) | called by muse, mutect2, varscan2
- GPIHBP1 | c.40T>C p.F14L | Missense Mutation (SNP) | VAF 24/449 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2
- HEATR1 | c.860T>C p.I287T | Missense Mutation (SNP) | VAF 8/250 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- HSPA5 | c.739_749del p.T247Yfs*9 | Frame Shift Del (DEL) | VAF 40/248 reads (16%) | called by mutect2, pindel, varscan2
- HTR1E | c.85C>G p.L29V | Missense Mutation (SNP) | VAF 94/225 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- INTS6L | c.984T>G p.F328L | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- IRAK4 | c.1072G>C p.E358Q | Missense Mutation (SNP) | VAF 56/304 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- JAKMIP2 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- LRFN3 | c.870G>T p.E290D | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- LRRN1 | c.1540A>G p.I514V | Missense Mutation (SNP) | VAF 210/398 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- MGA | c.7701G>T p.R2567S (on ENST00000219905 / NM_001164273.1; = p.R2358S on NM_001080541.2) | Missense Mutation (SNP) | VAF 79/185 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- MMACHC | c.377C>T p.A126V | Missense Mutation (SNP) | VAF 50/303 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- MRC1 | c.2251G>T p.E751* | Nonsense Mutation (SNP) | VAF 28/255 reads (11%) | called by muse, mutect2, varscan2
- MRGPRX2 | c.458T>G p.L153R | Missense Mutation (SNP) | VAF 71/227 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYH11 | c.1750G>C p.V584L | Missense Mutation (SNP) | VAF 135/508 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- NEPRO | c.1125G>C p.Q375H | Missense Mutation (SNP) | VAF 43/274 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- OTUD4 | c.2602C>T p.Q868* (on ENST00000447906 / NM_001366057.1; = p.Q803* on NM_001102653.1) | Nonsense Mutation (SNP) | VAF 47/311 reads (15%) | called by muse, mutect2, varscan2
- PSG11 | c.446C>G p.P149R | Missense Mutation (SNP) | VAF 50/136 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PSMD13 | c.577C>A p.Q193K | Missense Mutation (SNP) | VAF 107/173 reads (62%) | SIFT tolerated (0.45); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PTTG1 | c.265T>C p.S89P | Missense Mutation (SNP) | VAF 34/147 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- RBM6 | c.3043G>C p.D1015H | Missense Mutation (SNP) | VAF 75/99 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RC3H2 | c.2461G>C p.E821Q | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.029); called by mutect2, varscan2
- RECK | c.1259A>C p.K420T | Missense Mutation (SNP) | VAF 87/209 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RGS12 | c.1975A>T p.T659S | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- RPS6KB2 | c.970-41_974del p.X324_splice | Splice Site (DEL) | VAF 116/682 reads (17%) | called by mutect2, pindel
- RYR3 | c.8042_8048del p.V2681Gfs*89 (on ENST00000389232; = p.V2682Gfs*89 on NM_001036.6) | Frame Shift Del (DEL) | VAF 38/142 reads (27%) | called by mutect2, pindel, varscan2
- SACS | c.8591C>G p.P2864R | Missense Mutation (SNP) | VAF 46/358 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.154); called by mutect2, varscan2
- SPTBN2 | c.5548C>G p.Q1850E | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.805); called by muse, mutect2
- TLE4 | c.1819C>A p.H607N | Missense Mutation (SNP) | VAF 86/307 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- TRIM7 | c.388T>G p.C130G | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- TTC37 | c.1587A>T p.E529D | Missense Mutation (SNP) | VAF 67/154 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- TXNDC16 | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.44); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- WDR88 | c.382C>A p.L128M | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- WFDC9 | c.122G>A p.C41Y | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WT1 | c.1040A>G p.H347R | Missense Mutation (SNP) | VAF 128/387 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- ZNF469 | c.8146C>A p.P2716T (on ENST00000437464; = p.P2744T on NM_001367624.2) | Missense Mutation (SNP) | VAF 109/389 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- ABCC3 | c.2964C>A p.A988= | Silent (SNP) | VAF 286/419 reads (68%) | called by muse, mutect2, varscan2
- CACNA1C | c.2955C>A p.G985= | Silent (SNP) | VAF 62/175 reads (35%) | called by muse, mutect2, varscan2
- CFHR1 | c.96T>A p.I32= | Silent (SNP) | VAF 123/281 reads (44%) | called by muse, mutect2, varscan2
- CPLX3 | c.147G>A p.K49= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as COSV100547731; called by muse, mutect2, varscan2
- FGD2 | c.1713G>T p.R571= | Silent (SNP) | VAF 25/162 reads (15%) | called by muse, mutect2, varscan2
- FRAS1 | c.7044A>T p.T2348= | Silent (SNP) | VAF 54/175 reads (31%) | called by muse, mutect2, varscan2
- INPP5J | c.2118G>A p.T706= (on ENST00000331075 / NM_001284285.2; = p.T338= on NM_001002837.2) | Silent (SNP) | VAF 38/237 reads (16%) | catalogued as rs561550194; called by muse, mutect2, varscan2
- ITGAL | c.2883C>T p.I961= | Silent (SNP) | VAF 99/258 reads (38%) | catalogued as rs781698533; called by muse, mutect2, varscan2
- KAT8 | c.63C>A p.G21= | Silent (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2
- MAGEC1 | c.2748G>A p.A916= | Silent (SNP) | VAF 123/391 reads (31%) | catalogued as rs749815753, COSV53572525; called by muse, mutect2, varscan2
- NAALADL2 | c.1314C>T p.G438= | Silent (SNP) | VAF 7/102 reads (7%) | called by muse, mutect2
- PDE8B | c.693C>T p.H231= | Silent (SNP) | VAF 237/574 reads (41%) | catalogued as rs749278223; called by muse, mutect2, varscan2
- PDZD4 | c.471C>T p.G157= | Silent (SNP) | VAF 102/267 reads (38%) | called by muse, mutect2, varscan2
- SMAD5 | c.198C>T p.V66= | Silent (SNP) | VAF 24/138 reads (17%) | called by muse, mutect2, varscan2
- TCEAL2 | c.129C>T p.N43= | Silent (SNP) | VAF 42/170 reads (25%) | catalogued as COSV61197413; called by muse, mutect2
- TSGA10IP | c.153C>T p.C51= | Silent (SNP) | VAF 63/120 reads (53%) | called by muse, mutect2, varscan2
- WDR6 | c.1587G>A p.G529= | Silent (SNP) | VAF 37/152 reads (24%) | called by muse, mutect2, varscan2
- ZC3H7A | c.2589G>A p.G863= | Silent (SNP) | VAF 23/204 reads (11%) | called by muse, mutect2, varscan2
- CFAP52 | c.-10C>A | 5'UTR (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2, varscan2
- CNIH2 | c.82-815G>C | Intron (SNP) | VAF 81/260 reads (31%) | called by muse, mutect2, varscan2
- EPB41L4A | chr5:112419926 G>T | 5'Flank (SNP) | VAF 94/215 reads (44%) | called by muse, mutect2, varscan2
- FUS | c.*81C>T | 3'UTR (SNP) | VAF 148/439 reads (34%) | catalogued as rs768544815; called by mutect2, varscan2
- GABRR1 | c.123-1206C>T | Intron (SNP) | VAF 33/90 reads (37%) | catalogued as rs532171331; called by muse, mutect2, varscan2
- MAN2A2 | chr15:90904183 C>G | 5'Flank (SNP) | VAF 95/371 reads (26%) | called by muse, mutect2, varscan2
- MIR6080 | chr17:64780682 T>C | 5'Flank (SNP) | VAF 49/69 reads (71%) | called by muse, mutect2, varscan2
- OSR2 | c.-114-554C>A | Intron (SNP) | VAF 142/231 reads (61%) | called by muse, mutect2, varscan2
- PFDN5 | c.207+223T>G | Intron (SNP) | VAF 4/29 reads (14%) | called by muse, mutect2
- POTEG | c.811-1170T>A | Intron (SNP) | VAF 27/324 reads (8%) | called by muse, mutect2
- RGS11 | c.318+229G>T | Intron (SNP) | VAF 197/577 reads (34%) | called by muse, mutect2, varscan2
- S100B | c.139-782A>G | Intron (SNP) | VAF 26/133 reads (20%) | called by muse, mutect2, varscan2
